Somatic mutation profile of tumor specimen TCGA-93-A4JP-01A (aliquot TCGA-93-A4JP-01A-11D-A24P-08) from TCGA case TCGA-93-A4JP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.7 years (23,620 days).
Specimen TCGA-93-A4JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d486da5-c534-46de-894e-d96980f71dee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-A4JP-10A (Blood Derived Normal), aliquot TCGA-93-A4JP-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29447f6e-930e-4538-a469-b20dd40ef845

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 38, Silent 11, Nonsense Mutation 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 12/138 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2
- TP53 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | hotspot (GDC flag); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2631C>G p.D877E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV101275991; called by muse, mutect2
- AGER | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100426221, COSV61248342; called by muse, mutect2
- AHNAK | c.14768T>A p.L4923* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99948322; called by muse, mutect2
- ASPM | c.7056G>C p.M2352I | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.474); catalogued as COSV54124482, COSV54126118; called by muse, mutect2
- BMP2K | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99785231; called by muse, mutect2
- C11orf71 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100348401; called by muse, mutect2
- C16orf72 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100589078; called by muse, mutect2
- CEMIP | c.2880C>A p.D960E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779315054, COSV99586948; called by muse, mutect2
- CFAP298-TCP10L | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100291935; called by muse, mutect2
- COL15A1 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV100897846; called by muse, mutect2
- CPA1 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1554411117, COSV99163282; called by muse, mutect2
- FAM181A | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs1210196399, COSV50888079, COSV99967891; called by muse, mutect2
- GABRG1 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs1308305437, COSV99778365; called by muse, mutect2, varscan2
- GJA1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs755535373, CM166276; called by muse, mutect2, varscan2
- GRM5 | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1173489364, COSV59603502; called by muse, mutect2
- GTF3C3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.037); catalogued as COSV99826813; called by muse, mutect2
- HSPA2 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV99905030; called by muse, mutect2
- INTS6L | c.499A>T p.R167W | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878173; called by muse, mutect2
- KATNIP | c.551G>T p.R184I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99851494; called by muse, mutect2
- KCNH4 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV99237524; called by muse, mutect2
- MON2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99742975; called by muse, mutect2, varscan2
- MYB | c.1572G>T p.K524N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214989; called by muse, mutect2, varscan2
- OBSCN | c.1442A>T p.Q481L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV99481217; called by muse, mutect2
- OPTN | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs779278597, CD1512216, COSV99537622; called by muse, mutect2, varscan2
- PCDHB6 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV50701615; called by muse, mutect2
- PCNX1 | c.6898T>A p.W2300R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99456281; called by muse, mutect2
- PIK3R4 | c.3925A>T p.K1309* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100650511; called by muse, mutect2
- PMS1 | c.1962A>G p.I654M | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100575715; called by muse, mutect2
- PPP1R13L | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV62908419; called by muse, mutect2
- PRX | c.2926G>T p.E976* | Nonsense Mutation (SNP) | VAF 25/127 reads (20%) | catalogued as COSV99397814; called by muse, mutect2, varscan2
- PRX | c.411G>C p.K137N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99397821; called by muse, mutect2, varscan2
- RABEP1 | c.2128A>C p.K710Q | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV99336819; called by muse, mutect2, varscan2
- RASSF7 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100272674; called by muse, mutect2
- RB1 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1368390928, COSV57300027; called by muse, mutect2, varscan2
- SPATA25 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV99509977; called by muse, mutect2, varscan2
- SYNE1 | c.21335C>T p.A7112V (on ENST00000367255 / NM_182961.4; = p.A7041V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1458770104, COSV99570682; called by muse, mutect2
- TBL3 | c.1433A>T p.H478L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100224968; called by muse, mutect2, varscan2
- THADA | c.1984T>G p.W662G | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57676200; called by muse, mutect2
- ZBTB9 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101221778; called by muse, mutect2
- ZNF485 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100700239; called by muse, mutect2
- GADD45B | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PPM1A | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SIDT2 | c.193del p.V65Cfs*5 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- BRCA1 | c.4938C>T p.V1646= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV100524627; called by muse, mutect2
- DRG1 | c.990C>T p.I330= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100513720; called by muse, mutect2
- GABRA6 | c.636A>T p.G212= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99194696; called by muse, mutect2
- NTPCR | c.333C>T p.V111= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV100786727; called by muse, mutect2
- OR11G2 | c.402C>A p.G134= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs915819617, COSV100639989; called by muse, mutect2, varscan2
- OR4K15 | c.369C>A p.A123= (on ENST00000305051; = p.A99= on NM_001005486.1) | Silent (SNP) | VAF 11/189 reads (6%) | catalogued as COSV100520957, COSV59300713; called by muse, mutect2
- PCDHGB3 | c.1719G>A p.A573= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV53954936, COSV54070104; called by muse, mutect2
- SELPLG | c.915C>A p.V305= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV57311418, COSV57313419; called by muse, mutect2
- STAB1 | c.2775G>C p.V925= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100401949; called by muse, mutect2, varscan2
- UBA6 | c.393A>T p.P131= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV100451775; called by muse, mutect2, varscan2
- XDH | c.1839G>A p.R613= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV65151760; called by muse, mutect2
